Somatic mutation profile of tumor specimen TCGA-39-5036-01A (aliquot TCGA-39-5036-01A-01D-1441-08) from TCGA case TCGA-39-5036, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.8 years (26,963 days).
Specimen TCGA-39-5036-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 86bb3164-f0d4-45d2-ae0d-6f254597eb14.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-39-5036-11A (Solid Tissue Normal), aliquot TCGA-39-5036-11A-01D-1441-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1e298bd-693a-49f7-9911-0758a8996e75

The open-access MAF lists 270 somatic variants for this specimen: 206 protein-altering or splice-affecting, 55 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 176, Silent 55, Nonsense Mutation 13, Splice Site 7, Frame Shift Del 6, Intron 3, Frame Shift Ins 3, 3'UTR 2, RNA 2, Splice Region 1, 5'Flank 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC018630.4 | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.234); catalogued as COSV57392756; called by muse, mutect2
- ACSM5 | c.1685C>G p.T562R | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59375371; called by muse, mutect2, varscan2
- ADAMTS17 | c.605A>G p.K202R | Missense Mutation (SNP) | VAF 53/188 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as rs371369169; called by muse, mutect2, varscan2
- ADAMTS18 | c.982C>A p.L328I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51423966; called by muse, mutect2, varscan2
- ADAMTS19 | c.851C>T p.S284F | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.631); catalogued as COSV50806546, COSV99180725; called by muse, mutect2, varscan2
- ADCY1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); catalogued as COSV52043598; called by muse, mutect2, varscan2
- ADCY1 | c.2191C>G p.L731V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV52043607; called by muse, mutect2, varscan2
- ADGRG4 | c.3497C>A p.S1166Y | Missense Mutation (SNP) | VAF 129/179 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.166); catalogued as COSV54968649; called by muse, mutect2, varscan2
- AHI1 | c.3531A>G p.I1177M | Missense Mutation (SNP) | VAF 185/449 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV55637209; called by muse, mutect2, varscan2
- AKAP6 | c.2318A>C p.N773T | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV55235720; called by muse, mutect2, varscan2
- AMPH | c.1399-1G>C p.X467_splice | Splice Site (SNP) | VAF 42/87 reads (48%) | catalogued as COSV57759428; called by muse, mutect2, varscan2
- AMY2B | c.1159A>T p.I387F | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.052); catalogued as COSV63714754, COSV63717338; called by muse, mutect2, varscan2
- ANKRD30A | c.641G>A p.C214Y (on ENST00000611781; = p.C158Y on NM_052997.2) | Missense Mutation (SNP) | VAF 29/254 reads (11%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.902); catalogued as COSV64622865; called by muse, mutect2, varscan2
- ANKRD30A | c.2020G>A p.E674K (on ENST00000611781; = p.E618K on NM_052997.2) | Missense Mutation (SNP) | VAF 28/108 reads (26%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.678); catalogued as COSV64617755; called by muse, mutect2, varscan2
- API5 | c.459A>C p.K153N | Missense Mutation (SNP) | VAF 11/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV66635368; called by muse, mutect2
- APOL4 | c.989G>T p.W330L (on ENST00000352371 / NM_145660.2; = p.W327L on NM_030643.4) | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.009); catalogued as rs761989460, COSV100274123; called by muse, mutect2, varscan2
- ARAP1 | c.2269G>T p.G757C (on ENST00000393609 / NM_001040118.2; = p.G512C on NM_015242.4) | Missense Mutation (SNP) | VAF 116/342 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV61990764, COSV61995652; called by muse, mutect2, varscan2
- ARIH2 | c.376C>G p.P126A | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV62706022, COSV62706572; called by muse, mutect2, varscan2
- ASAP1 | c.1555A>G p.M519V | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs1211305056, COSV63055114; called by muse, mutect2, varscan2
- ASTN1 | c.2518A>G p.T840A | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV56083577, COSV56088115; called by muse, mutect2, varscan2
- BMP5 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.368); catalogued as COSV63707031; called by muse, mutect2, varscan2
- BRINP3 | c.1835T>C p.L612S | Missense Mutation (SNP) | VAF 139/459 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.228); catalogued as COSV66543123; called by muse, mutect2, varscan2
- BRINP3 | c.1349T>A p.L450Q | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV66543126; called by muse, mutect2, varscan2
- C5orf49 | c.341A>T p.N114I | Missense Mutation (SNP) | VAF 12/401 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.056); catalogued as COSV57903665; called by muse, mutect2
- CAPN10 | c.490C>A p.H164N | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.3); catalogued as COSV54380182; called by muse, mutect2, varscan2
- CCDC83 | c.106A>T p.K36* | Nonsense Mutation (SNP) | VAF 9/67 reads (13%) | catalogued as COSV54705327; called by muse, mutect2, varscan2
- CCDC85A | c.905C>A p.P302H | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68155970; called by muse, mutect2, varscan2
- CCKAR | c.284T>C p.M95T | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs943601131, COSV55164369; called by muse, mutect2, varscan2
- CCN3 | c.299G>C p.G100A | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52385551; called by muse, mutect2, varscan2
- CCNA1 | c.1080G>T p.R360S | Missense Mutation (SNP) | VAF 50/115 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.395); catalogued as COSV55224575; called by muse, mutect2, varscan2
- CDC40 | c.1709G>T p.G570V | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57012781; called by muse, mutect2, varscan2
- CEP120 | c.2470A>C p.T824P | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV60269044; called by muse, mutect2, varscan2
- CEP126 | c.1367G>C p.C456S | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as COSV54831543; called by muse, mutect2
- CEP83 | c.1722T>G p.H574Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.602); catalogued as COSV60411639; called by muse, mutect2, varscan2
- CFAP44 | c.455T>C p.L152P | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs769728207, COSV55616359; called by muse, mutect2, varscan2
- CHAT | c.1061C>A p.T354K | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CM055128, COSV60322745, COSV60334430; called by muse, mutect2, varscan2
- CPB1 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 37/164 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV51577419; called by muse, mutect2, varscan2
- CRISP2 | c.183G>T p.M61I | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59256050, COSV59257207; called by muse, mutect2, varscan2
- CROT | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 18/228 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.152); catalogued as rs534687382, COSV58977193; called by muse, mutect2
- CSMD3 | c.6022A>T p.S2008C (on ENST00000297405 / NM_001363185.1; = p.S1904C on NM_052900.3) | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV52337173; called by muse, mutect2, varscan2
- CUBN | c.10735T>A p.S3579T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.596); catalogued as COSV64728733; called by muse, mutect2
- CXorf66 | c.80C>G p.S27C | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); catalogued as COSV65169877; called by muse, mutect2, varscan2
- CYP4F12 | c.1436A>C p.K479T | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV61177066; called by muse, mutect2, varscan2
- DCAF8 | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 41/109 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58786428; called by muse, mutect2, varscan2
- DCC | c.1138G>T p.V380L | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.544); catalogued as COSV59140548; called by muse, mutect2, varscan2
- DCDC1 | c.2953G>A p.G985R (on ENST00000597505 / NM_001367979.1; = p.G92R on NM_020869.3) | Missense Mutation (SNP) | VAF 52/231 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60305019; called by muse, mutect2, varscan2
- DDX6 | c.469C>T p.R157W | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs782757060, COSV50592876; called by muse, mutect2, varscan2
- DEPDC5 | c.1875G>T p.M625I (on ENST00000400246; = p.M703I on NM_014662.5) | Missense Mutation (SNP) | VAF 143/469 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as COSV56712276; called by muse, mutect2, varscan2
- DIDO1 | c.1465A>G p.S489G | Missense Mutation (SNP) | VAF 53/259 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV56635228; called by muse, mutect2, varscan2
- DIP2B | c.4721A>T p.Y1574F | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.318); catalogued as COSV56593163; called by muse, mutect2, varscan2
- DLX5 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV56031553; called by muse, mutect2, varscan2
- DMD | c.10081A>G p.T3361A | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV58957835; called by muse, mutect2
- DNASE2B | c.1012T>C p.F338L | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.43); PolyPhen benign (0.085); catalogued as COSV65738107; called by muse, mutect2, varscan2
- DPP6 | c.2117T>A p.V706E (on ENST00000377770 / NM_001364500.2; = p.V644E on NM_001936.5) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59648660; called by muse, mutect2
- DROSHA | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV60783667; called by muse, mutect2, varscan2
- DSEL | c.2318G>T p.R773M | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as COSV59495344; called by muse, mutect2
- DUSP4 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0); catalogued as COSV53548041; called by muse, mutect2
- ELN | c.1465G>A p.V489I | Missense Mutation (SNP) | VAF 36/361 reads (10%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs781846233, COSV52716410; called by muse, mutect2, varscan2
- EOMES | c.1576C>A p.P526T | Missense Mutation (SNP) | VAF 104/205 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.038); catalogued as COSV55415959; called by muse, mutect2, varscan2
- EPHA5 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56678116; called by muse, varscan2
- ERICH3 | c.1040C>A p.P347H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58601214; called by muse, mutect2, varscan2
- EVI5 | c.135G>T p.M45I | Missense Mutation (SNP) | VAF 67/242 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV64830588; called by muse, mutect2, varscan2
- EXTL3 | c.2612C>T p.S871F | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV55040807; called by muse, mutect2, varscan2
- FAM102B | c.170G>A p.R57K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV64241466; called by muse, mutect2
- FCRL3 | c.460G>T p.V154F | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV63845436; called by muse, mutect2, varscan2
- FGA | c.163T>A p.C55S | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM116638, CM153761, COSV57401892; called by muse, mutect2, varscan2
- FOXP2 | c.1568G>A p.R523K | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.04); catalogued as COSV63494931; called by muse, mutect2, varscan2
- FPR3 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs769949526, COSV59332526; called by muse, mutect2, varscan2
- FUT5 | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 11/90 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV53139151; called by muse, mutect2, varscan2
- GABRA5 | c.1327G>T p.V443F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as COSV59486532; called by muse, mutect2, varscan2
- GDI1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV50133490; called by muse, mutect2, varscan2
- GGCT | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 64/137 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV50040814, COSV50041077; called by muse, mutect2, varscan2
- GNL1 | c.1442-2A>T p.X481_splice | Splice Site (SNP) | VAF 52/94 reads (55%) | catalogued as COSV64921533; called by muse, mutect2, varscan2
- GOLGA4 | c.2695C>T p.Q899* | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | catalogued as COSV62714253; called by muse, mutect2, varscan2
- GPRASP2 | c.1177G>C p.A393P | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.543); catalogued as COSV59992339, COSV59992672; called by muse, mutect2
- GRB14 | c.397G>C p.V133L | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.074); catalogued as COSV55741061, COSV55744268; called by muse, mutect2, varscan2
- GRIA3 | c.998G>A p.R333Q | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as rs768229296, COSV52049045, COSV52060711; called by muse, mutect2, varscan2
- GRIK2 | c.2270G>T p.G757V | Missense Mutation (SNP) | VAF 82/258 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59777277; called by muse, mutect2, varscan2
- HDX | c.279C>G p.S93R | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.097); catalogued as COSV52983448; called by muse, mutect2
- HEPH | c.2155C>A p.P719T (on ENST00000343002; = p.P452T on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.044); catalogued as COSV57973556; called by muse, mutect2, varscan2
- HLCS | c.52+1G>A p.X18_splice | Splice Site (SNP) | VAF 42/102 reads (41%) | catalogued as COSV60798967; called by muse, mutect2, varscan2
- HMCN1 | c.227G>A p.R76K | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.58); PolyPhen benign (0.079); catalogued as COSV54878387, COSV54946316; called by muse, mutect2, varscan2
- HOXC4 | c.64G>C p.E22Q | Missense Mutation (SNP) | VAF 125/272 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV57700874; called by muse, mutect2, varscan2
- IFT43 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs751183646, COSV53141942; called by muse, mutect2, varscan2
- IGHV3-23 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 69/540 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.236); catalogued as rs1164728836; called by muse, mutect2, varscan2
- IGHV3-23 | c.197G>A p.W66* | Nonsense Mutation (SNP) | VAF 69/541 reads (13%) | catalogued as rs782358535; called by muse, mutect2, varscan2
- IGHV7-81 | c.48T>C p.G16= | Splice Region (SNP) | VAF 51/192 reads (27%) | catalogued as rs1178159902; called by muse, mutect2, varscan2
- IGSF3 | c.982A>G p.M328V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59599461; called by muse, mutect2, varscan2
- INTS1 | c.2948A>T p.Q983L | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV67180096; called by muse, mutect2, varscan2
- IPO11 | c.874A>G p.I292V | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.279); catalogued as COSV57583674; called by muse, mutect2
- IPO11 | c.1703T>G p.L568R | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57583680; called by muse, mutect2, varscan2
- IPO8 | c.2075-1G>A p.X692_splice | Splice Site (SNP) | VAF 6/91 reads (7%) | catalogued as COSV56246605; called by muse, mutect2
- KCNH5 | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 21/125 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV59780215; called by muse, mutect2, varscan2
- KCNH8 | c.1018C>T p.R340C | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1379582412, COSV60460065; called by muse, mutect2, varscan2
- KEAP1 | c.1268G>T p.G423V | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV50654851; called by muse, mutect2, varscan2
- KIAA1755 | c.290C>A p.P97H | Missense Mutation (SNP) | VAF 20/243 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54081429; called by muse, mutect2
- KMT2C | c.7903C>T p.Q2635* | Nonsense Mutation (SNP) | VAF 68/189 reads (36%) | catalogued as COSV51509882; called by muse, mutect2, varscan2
- KRT222 | c.725T>A p.L242* | Nonsense Mutation (SNP) | VAF 73/131 reads (56%) | catalogued as COSV67499414; called by muse, mutect2, varscan2
- LAMA4 | c.5380C>T p.R1794C (on ENST00000230538 / NM_001105206.3; = p.R1787C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781802725, COSV57895259; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAPTM4B | c.10C>T p.R4W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.353); catalogued as rs1376613965, COSV63393064; called by muse, mutect2, varscan2
- LCE4A | c.197A>G p.H66R | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs199914704, COSV59267450; called by muse, mutect2, varscan2
- LILRA2 | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as rs765040443, COSV52197866; called by muse, mutect2, varscan2
- LRP1B | c.3090C>A p.D1030E | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV67249407, COSV67280566; called by muse, mutect2, varscan2
- LRRIQ1 | c.4961A>G p.H1654R | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as COSV67839725; called by muse, mutect2, varscan2
- LRRK1 | c.1919A>C p.K640T | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52627884; called by muse, mutect2, varscan2
- LRRK2 | c.4538T>C p.I1513T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54173408; called by muse, mutect2
- MBD5 | c.2903C>A p.S968* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV68697953, COSV68699147; called by muse, mutect2, varscan2
- MED17 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.123); catalogued as rs1270839943, COSV52603495; called by muse, mutect2, varscan2
- MMP16 | c.151G>T p.G51C | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54192242, COSV99686584; called by muse, mutect2, varscan2
- MMS22L | c.1486A>G p.M496V | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV51527417; called by muse, mutect2, varscan2
- MROH9 | c.174G>T p.Q58H | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV63011829; called by muse, mutect2
- MSH4 | c.2070A>T p.L690F | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as COSV54213728; called by muse, mutect2, varscan2
- MTERF3 | c.382G>T p.E128* | Nonsense Mutation (SNP) | VAF 36/87 reads (41%) | catalogued as COSV54634537, COSV54634881; called by muse, mutect2, varscan2
- MUC17 | c.12874G>T p.D4292Y | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100071245, COSV60306036; called by muse, mutect2, varscan2
- MXRA5 | c.4889C>A p.S1630Y | Missense Mutation (SNP) | VAF 146/212 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV54252934; called by muse, mutect2, varscan2
- MYCBP2 | c.13447A>G p.T4483A (on ENST00000357337; = p.T4521A on NM_015057.5) | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV62041836; called by muse, mutect2, varscan2
- MYH6 | c.1548G>T p.M516I | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV62455068; called by muse, mutect2, varscan2
- MYH8 | c.5433del p.K1812Rfs*39 | Frame Shift Del (DEL) | VAF 65/160 reads (41%) | catalogued as COSV67959127; called by mutect2, pindel, varscan2
- MYL3 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.116); catalogued as COSV52768374; called by muse, mutect2, varscan2
- MYO18B | c.950A>T p.K317M | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.875); catalogued as COSV59150734; called by muse, mutect2, varscan2
- MYO3A | c.2281G>C p.D761H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV56334726, COSV99781144; called by muse, mutect2, varscan2
- MYOF | c.4690G>C p.E1564Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV63711511; called by muse, mutect2, varscan2
- NAGK | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV54904719; called by muse, mutect2, varscan2
- NAP1L2 | c.338T>A p.L113* | Nonsense Mutation (SNP) | VAF 57/85 reads (67%) | catalogued as COSV65173160; called by muse, mutect2, varscan2
- NPAP1 | c.3463C>T p.L1155F | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV61512112; called by muse, mutect2
- NSF | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV56577020; called by muse, mutect2, varscan2
- NSFL1C | c.421C>G p.P141A | Missense Mutation (SNP) | VAF 101/415 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as COSV53795482; called by muse, mutect2, varscan2
- OR10A4 | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1564922932, COSV65842708; called by muse, mutect2, varscan2
- OR10J3 | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 47/187 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100171720, COSV59955792; called by muse, mutect2, varscan2
- OR5AS1 | c.344T>A p.L115Q | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57982000, COSV57983386; called by muse, mutect2, varscan2
- OR8B2 | c.459G>T p.L153F | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV66665601; called by muse, mutect2, varscan2
- OSBPL6 | c.2648G>T p.R883I | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51931998; called by muse, mutect2, varscan2
- PCDHA12 | c.2123C>A p.S708Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV56551299; called by muse, mutect2, varscan2
- PCDHB7 | c.977G>A p.G326E | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV50825465; called by muse, mutect2, varscan2
- PCDHGA11 | c.1831A>T p.K611* | Nonsense Mutation (SNP) | VAF 39/89 reads (44%) | catalogued as rs1235938743, COSV54046401; called by muse, mutect2, varscan2
- PCDHGA3 | c.80G>C p.G27A | Missense Mutation (SNP) | VAF 94/199 reads (47%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.32); catalogued as COSV54046385; called by muse, mutect2, varscan2
- PDCL2 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55263323; called by muse, mutect2, varscan2
- PDCL2 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55263336; called by muse, mutect2, varscan2
- PDZD2 | c.1130G>T p.R377M | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56874755; called by muse, mutect2, varscan2
- PDZD2 | c.2301G>C p.K767N | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56874764; called by muse, mutect2
- PIWIL3 | c.1150A>T p.K384* | Nonsense Mutation (SNP) | VAF 11/100 reads (11%) | catalogued as rs1338722809, COSV59998588; called by muse, mutect2, varscan2
- PLA1A | c.420C>A p.S140R | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56334104; called by muse, mutect2, varscan2
- PLBD2 | c.1392del p.N465Tfs*14 | Frame Shift Del (DEL) | VAF 55/197 reads (28%) | catalogued as COSV55105461; called by mutect2, pindel, varscan2
- PLCE1 | c.1099A>G p.K367E | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as COSV53374513; called by muse, mutect2, varscan2
- PLD5 | c.283G>T p.D95Y (on ENST00000442594; = p.D33Y on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/202 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59154616, COSV59171009; called by muse, mutect2, varscan2
- PLOD1 | c.1733A>T p.Q578L | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV52151144; called by muse, mutect2, varscan2
- PPP4R2 | c.304C>T p.Q102* | Nonsense Mutation (SNP) | VAF 32/66 reads (48%) | catalogued as COSV55598414; called by muse, mutect2, varscan2
- PRTG | c.1942A>T p.I648F | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.327); catalogued as COSV66838996; called by muse, mutect2, varscan2
- PRXL2A | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64691291; called by muse, mutect2, varscan2
- PTK6 | c.392G>C p.R131P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV53915971, COSV53918733; called by mutect2, varscan2
- PTPRJ | c.2756A>G p.N919S | Missense Mutation (SNP) | VAF 84/213 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1368991431, COSV69249895; called by muse, mutect2, varscan2
- PTPRR | c.895C>A p.L299M | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.201); catalogued as COSV51749651; called by muse, mutect2, varscan2
- PTTG2 | c.380G>T p.S127I | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV54728305; called by muse, mutect2, varscan2
- REG3A | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs190335034, COSV59412327; called by muse, mutect2, varscan2
- RHBDD1 | c.842G>T p.S281I | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58129437, COSV58132176; called by muse, mutect2, varscan2
- RIPK3 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 48/149 reads (32%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs748449238, COSV53477835; called by muse, mutect2, varscan2
- RNF43 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs200066146, COSV68456876; called by muse, mutect2
- RP1L1 | c.7038A>T p.E2346D | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV66761072; called by muse, mutect2, varscan2
- RYR2 | c.12853T>G p.S4285A | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.366); catalogued as COSV63678474; called by muse, mutect2, varscan2
- SEMA3A | c.1517C>A p.T506K | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs748598600, COSV54890652; called by muse, mutect2, varscan2
- SLC13A2 | c.388C>A p.L130M | Missense Mutation (SNP) | VAF 63/101 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as rs1555603152, COSV58999237; called by muse, mutect2, varscan2
- SLC17A3 | c.559T>A p.S187T | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV57761739; called by muse, mutect2, varscan2
- SLC39A12 | c.668G>T p.G223V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV101070120, COSV66202913; called by muse, mutect2, varscan2
- SLC6A3 | c.1412T>A p.V471D | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV54370205; called by muse, mutect2
- SLC6A5 | c.2016G>T p.Q672H | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV54233114; called by muse, mutect2, varscan2
- SLCO6A1 | c.109G>A p.G37R | Missense Mutation (SNP) | VAF 123/311 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1415916913, COSV65806919; called by muse, mutect2, varscan2
- SP110 | c.336G>A p.W112* | Nonsense Mutation (SNP) | VAF 10/96 reads (10%) | catalogued as rs1195830644, COSV51278029; called by muse, mutect2, varscan2
- SPAG17 | c.4808T>C p.L1603S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as COSV60469676; called by muse, mutect2, varscan2
- STRADB | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV52044069, COSV52044827; called by muse, mutect2, varscan2
- STYX | c.197A>T p.N66I | Missense Mutation (SNP) | VAF 8/246 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.234); catalogued as COSV63464040; called by muse, mutect2
- SULF1 | c.2184G>T p.K728N | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV52694811; called by muse, mutect2, varscan2
- SULT2A1 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 79/169 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV55766652; called by muse, mutect2, varscan2
- SYNE2 | c.5353-2A>C p.X1785_splice | Splice Site (SNP) | VAF 19/89 reads (21%) | catalogued as COSV59972696; called by muse, mutect2, varscan2
- SYTL2 | c.1513A>G p.R505G | Missense Mutation (SNP) | VAF 35/105 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV100314280, COSV60364522; called by muse, mutect2, varscan2
- TAF1 | c.1118G>A p.G373D (on ENST00000373790 / NM_138923.4; = p.G394D on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/123 reads (63%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV52126983; called by muse, mutect2, varscan2
- TAF2 | c.3214G>T p.G1072W | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65421769; called by muse, mutect2, varscan2
- TAF2 | c.1517C>T p.S506F | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.092); catalogued as COSV65421777; called by muse, mutect2
- TBX5 | c.389C>A p.A130D | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); catalogued as COSV59864637, COSV59866044; called by muse, mutect2, varscan2
- TDP1 | c.1444G>T p.A482S | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.926); catalogued as COSV59646062; called by muse, mutect2, varscan2
- TENM1 | c.178C>T p.Q60* | Nonsense Mutation (SNP) | VAF 133/223 reads (60%) | catalogued as COSV64445491; called by muse, mutect2, varscan2
- TENM3 | c.4293G>T p.Q1431H | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV69318918, COSV69321240; called by muse, mutect2, varscan2
- TEX15 | c.5328A>C p.E1776D (on ENST00000256246; = p.E2159D on NM_001350162.2) | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); catalogued as COSV56355187; called by muse, mutect2, varscan2
- TMEM168 | c.1326G>C p.L442F | Missense Mutation (SNP) | VAF 4/96 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.6); catalogued as COSV57182786; called by muse, mutect2
- TMEM184A | c.989C>G p.A330G | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.15); catalogued as COSV52476206; called by muse, varscan2
- TNNI3K | c.2126G>T p.R709I | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as COSV53953040; called by muse, mutect2, varscan2
- TPH1 | c.470+1G>A p.X157_splice | Splice Site (SNP) | VAF 36/138 reads (26%) | catalogued as COSV51460923; called by muse, mutect2, varscan2
- TRAF3 | c.1241A>G p.Y414C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.604); catalogued as COSV61027840; called by muse, mutect2, varscan2
- TUBA3C | c.1316C>T p.S439F | Missense Mutation (SNP) | VAF 9/171 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV68029782; called by muse, mutect2
- USP26 | c.1944C>G p.F648L | Missense Mutation (SNP) | VAF 12/100 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV63708820, COSV63709977; called by muse, mutect2, varscan2
- USP7 | c.700T>G p.F234V | Missense Mutation (SNP) | VAF 16/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61217881; called by muse, mutect2
- VEGFC | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54607903; called by muse, mutect2, varscan2
- VIM | c.560A>G p.E187G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV56408042; called by muse, mutect2, varscan2
- WDFY3 | c.304+2T>C p.X102_splice | Splice Site (SNP) | VAF 7/142 reads (5%) | catalogued as COSV55715485; called by muse, mutect2
- WTIP | c.710A>T p.Q237L | Missense Mutation (SNP) | VAF 16/161 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV54330742; called by muse, mutect2
- YAF2 | c.398A>T p.K133I | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59892837; called by muse, mutect2, varscan2
- ZNF536 | c.2402A>C p.H801P | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62835690; called by mutect2, varscan2
- ZNF578 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as COSV69735970, COSV69737797; called by muse, mutect2, varscan2
- ZNF609 | c.778C>G p.L260V | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.889); catalogued as COSV58591025; called by muse, mutect2, varscan2
- ZPLD1 | c.7C>A p.Q3K (on ENST00000466937 / NM_001329788.1; = p.Q19K on NM_175056.2) | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV60356509; called by muse, mutect2
- KMT2D | c.5783del p.G1928Vfs*119 | Frame Shift Del (DEL) | VAF 52/119 reads (44%) | called by mutect2, pindel, varscan2
- LRP4 | c.2889del p.W963Cfs*12 | Frame Shift Del (DEL) | VAF 32/168 reads (19%) | called by mutect2, pindel, varscan2
- PLCB4 | c.1273dup p.E425Gfs*14 | Frame Shift Ins (INS) | VAF 17/103 reads (17%) | called by mutect2, pindel, varscan2
- RGS22 | c.2706_2710del p.K902Nfs*4 | Frame Shift Del (DEL) | VAF 20/78 reads (26%) | called by mutect2, pindel, varscan2
- TCP1 | c.587dup p.N196Kfs*43 | Frame Shift Ins (INS) | VAF 22/140 reads (16%) | called by pindel, varscan2
- TP53 | c.429_430insA p.Q144Tfs*5 | Frame Shift Ins (INS) | VAF 34/74 reads (46%) | called by mutect2, pindel, varscan2
- TRPC3 | c.1375_1376delinsA p.F459Mfs*2 (on ENST00000379645 / NM_001366479.2; = p.F386Mfs*2 on NM_003305.2) | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | called by pindel, varscan2*
- ADAMTS18 | c.1779C>A p.S593= | Silent (SNP) | VAF 95/319 reads (30%) | catalogued as COSV51398793, COSV51423953; called by muse, mutect2, varscan2
- ANK2 | c.8358T>A p.A2786= | Silent (SNP) | VAF 46/75 reads (61%) | catalogued as COSV52192270; called by muse, mutect2, varscan2
- APBB2 | c.225C>T p.I75= | Silent (SNP) | VAF 56/153 reads (37%) | catalogued as COSV55964050; called by muse, mutect2, varscan2
- ATP10A | c.1185C>T p.D395= | Silent (SNP) | VAF 12/159 reads (8%) | catalogued as COSV63525857; called by muse, mutect2
- BARHL2 | c.141C>T p.A47= | Silent (SNP) | VAF 62/171 reads (36%) | catalogued as rs768178843, COSV100966111, COSV64982162; called by muse, mutect2, varscan2
- BRPF1 | c.3469C>T p.L1157= | Silent (SNP) | VAF 24/309 reads (8%) | catalogued as COSV57355417; called by muse, mutect2
- CACNA1C | c.3822A>G p.K1274= | Silent (SNP) | VAF 11/56 reads (20%) | catalogued as rs1057524175, COSV59779337; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH19 | c.465C>A p.A155= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV50955038; called by muse, mutect2, varscan2
- CDH23 | c.1329T>C p.Y443= | Silent (SNP) | VAF 86/223 reads (39%) | catalogued as rs1459371535, COSV54955289; called by muse, mutect2, varscan2
- CLEC4M | c.882C>G p.T294= | Silent (SNP) | VAF 40/135 reads (30%) | catalogued as COSV50218647, COSV50225913; called by muse, mutect2, varscan2
- CR1 | c.957G>A p.G319= (on ENST00000367051; = p.G769= on NM_000651.6) | Silent (SNP) | VAF 12/84 reads (14%) | called by mutect2, varscan2
- DAZL | c.615A>T p.V205= | Silent (SNP) | VAF 19/42 reads (45%) | catalogued as COSV51714767; called by muse, mutect2, varscan2
- DOCK2 | c.120G>T p.T40= | Silent (SNP) | VAF 46/89 reads (52%) | catalogued as rs531692992, COSV56992060, COSV99910746; called by muse, mutect2, varscan2
- EPHA5 | c.1260C>A p.G420= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs760713555, COSV56678124; called by muse, varscan2
- FIBIN | c.255C>A p.T85= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV59413671; called by muse, mutect2, varscan2
- FSIP1 | c.837G>T p.L279= | Silent (SNP) | VAF 42/144 reads (29%) | catalogued as COSV63227267; called by muse, mutect2, varscan2
- GABRG1 | c.714T>C p.F238= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as COSV54962751; called by muse, mutect2, varscan2
- IFT57 | c.222T>C p.F74= | Silent (SNP) | VAF 22/133 reads (17%) | catalogued as COSV52712633; called by muse, mutect2, varscan2
- IL16 | c.3429A>G p.R1143= (on ENST00000302987 / NM_172217.5; = p.R442= on NM_004513.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/165 reads (4%) | catalogued as COSV57156231; called by muse, mutect2
- IRF3 | c.831C>T p.A277= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1283577425; called by muse, mutect2
- ISY1-RAB43 | c.177G>A p.Q59= | Silent (SNP) | VAF 29/147 reads (20%) | catalogued as COSV56443577, COSV99060235; called by muse, mutect2, varscan2
- ITGAV | c.75A>G p.L25= | Silent (SNP) | VAF 18/113 reads (16%) | catalogued as rs144478131; called by muse, mutect2, varscan2
- KCNF1 | c.1419C>T p.S473= | Silent (SNP) | VAF 15/94 reads (16%) | catalogued as rs1446025791, COSV54465872; called by muse, mutect2, varscan2
- KCNMB2 | c.663G>A p.Q221= | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs1367668075, COSV64202234; called by muse, mutect2
- LHPP | c.141G>A p.R47= | Silent (SNP) | VAF 3/43 reads (7%) | catalogued as rs1348344635, COSV64331789; called by muse, mutect2
- MED13L | c.4137G>A p.P1379= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs200776562, COSV56121816, COSV56131669; called by muse, mutect2, varscan2
- MGAM | c.3742C>T p.L1248= | Silent (SNP) | VAF 22/478 reads (5%) | catalogued as COSV72075166; called by muse, mutect2
- MSANTD4 | c.969G>A p.Q323= | Silent (SNP) | VAF 8/206 reads (4%) | catalogued as COSV57287061; called by muse, mutect2
- MSH4 | c.1527A>G p.V509= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as COSV54213719; called by muse, mutect2, varscan2
- MTHFSD | c.789G>A p.P263= (on ENST00000360900 / NM_001159377.2; = p.P262= on NM_022764.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as rs753956433, COSV59804999; called by muse, mutect2
- MTR | c.1311C>T p.S437= | Silent (SNP) | VAF 28/228 reads (12%) | catalogued as rs777192214, COSV63966515; called by muse, mutect2, varscan2
- MUC16 | c.39981C>A p.L13327= | Silent (SNP) | VAF 88/223 reads (39%) | catalogued as COSV66697271; called by muse, mutect2, varscan2
- NEPRO | c.1044G>C p.V348= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV58724650; called by muse, mutect2, varscan2
- PGA5 | c.1149C>G p.G383= | Silent (SNP) | VAF 67/296 reads (23%) | catalogued as COSV56717215; called by muse, mutect2, varscan2
- PLAG1 | c.1359T>A p.V453= | Silent (SNP) | VAF 18/164 reads (11%) | catalogued as COSV57616134; called by muse, mutect2
- PSMC3 | c.876C>T p.G292= | Silent (SNP) | VAF 85/253 reads (34%) | catalogued as COSV54083313; called by muse, mutect2, varscan2
- PTGER3 | c.861C>A p.I287= | Silent (SNP) | VAF 29/112 reads (26%) | catalogued as COSV60698687, COSV60698815; called by muse, mutect2, varscan2
- PTPRB | c.1227G>A p.R409= | Silent (SNP) | VAF 51/193 reads (26%) | catalogued as COSV54255546; called by muse, mutect2, varscan2
- RHD | c.642C>G p.L214= | Silent (SNP) | VAF 8/236 reads (3%) | catalogued as COSV59647472; called by muse, mutect2
- RNF20 | c.2145G>A p.Q715= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as COSV66662544; called by muse, mutect2, varscan2
- ROS1 | c.1953A>T p.A651= | Silent (SNP) | VAF 97/243 reads (40%) | catalogued as COSV63862417; called by muse, mutect2, varscan2
- RSBN1 | c.2212A>C p.R738= | Silent (SNP) | VAF 12/232 reads (5%) | catalogued as rs1178292018, COSV54735770; called by muse, mutect2
- RSPO3 | c.576A>T p.P192= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV63153353; called by muse, mutect2, varscan2
- SENP5 | c.1656G>T p.R552= | Silent (SNP) | VAF 31/147 reads (21%) | catalogued as COSV60210833; called by muse, mutect2, varscan2
- SLC11A2 | c.225C>T p.Y75= (on ENST00000394904 / NM_001379455.1; = p.Y46= on NM_000617.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as rs1268140867, COSV50377106; called by muse, mutect2
- SLC12A1 | c.2334G>T p.V778= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV66800454; called by muse, mutect2, varscan2
- SYNM | c.4530G>T p.G1510= (on ENST00000336292 / NM_145728.3; = p.G1198= on NM_015286.6) | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as COSV50444988; called by muse, mutect2, varscan2
- TAAR6 | c.282G>A p.V94= | Silent (SNP) | VAF 41/156 reads (26%) | catalogued as COSV51585044; called by muse, mutect2, varscan2
- TCAF1 | c.570G>A p.T190= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as rs776204839, COSV63517685; called by muse, mutect2, varscan2
- TNFRSF9 | c.432G>A p.K144= | Silent (SNP) | VAF 19/86 reads (22%) | catalogued as rs541005362, COSV66349758; called by muse, mutect2, varscan2
- TNIP2 | c.345C>G p.P115= | Silent (SNP) | VAF 28/99 reads (28%) | catalogued as rs143687899; called by muse, mutect2, varscan2
- TTN | c.74478T>C p.A24826= (on ENST00000591111; = p.A17402= on NM_003319.4) | Silent (SNP) | VAF 71/286 reads (25%) | catalogued as COSV60387761; called by muse, mutect2, varscan2
- UBR1 | c.534A>T p.S178= | Silent (SNP) | VAF 27/95 reads (28%) | catalogued as COSV51937254; called by muse, mutect2, varscan2
- UNC13D | c.2484G>A p.V828= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV52888029; called by muse, mutect2, varscan2
- UTP18 | c.13C>A p.R5= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV56585528; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852244 G>A | 3'Flank (SNP) | VAF 6/25 reads (24%) | catalogued as rs1026127481; called by muse, mutect2, varscan2
- GPR78 | c.*2G>T | 3'UTR (SNP) | VAF 9/61 reads (15%) | catalogued as COSV101223985; called by muse, mutect2, varscan2
- LIN9 | c.244+475G>T | Intron (SNP) | VAF 25/106 reads (24%) | catalogued as COSV60247290; called by muse, mutect2, varscan2
- LINC01600 | n.931G>T | RNA (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- MAF | c.*4268G>A | 3'UTR (SNP) | VAF 7/16 reads (44%) | catalogued as rs377735141; called by muse, mutect2, varscan2
- NANOS3 | chr19:13874992 G>T | 5'Flank (SNP) | VAF 28/75 reads (37%) | called by muse, mutect2, varscan2
- NRXN3 | c.989-7407G>T | Intron (SNP) | VAF 50/188 reads (27%) | called by muse, mutect2, varscan2
- NXF5 | n.853A>T | RNA (SNP) | VAF 44/77 reads (57%) | catalogued as COSV53793834; called by muse, mutect2, varscan2
- TPH2 | c.609-10823A>C | Intron (SNP) | VAF 6/105 reads (6%) | catalogued as COSV100422097; called by muse, mutect2
